Somatic mutation profile of tumor specimen TCGA-KV-A74V-01A (aliquot TCGA-KV-A74V-01A-11D-A33Q-10) from TCGA case TCGA-KV-A74V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 40.6 years (14,834 days).
Specimen TCGA-KV-A74V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7936a0c7-03ad-4ee9-a752-9929079f16ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KV-A74V-10A (Blood Derived Normal), aliquot TCGA-KV-A74V-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/505e0bd9-689e-4e03-8e19-637c7c60d27d

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Frame Shift Del 2, Silent 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LPL | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118204062, CM910265, CM962613, COSV100255676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.4581dup p.E1528* | Frame Shift Ins (INS) | VAF 9/91 reads (10%) | catalogued as rs137854329; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATOH1 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100024582; called by muse, mutect2, varscan2
- BRD1 | c.2713G>A p.A905T (on ENST00000216267 / NM_001349940.1; = p.A1036T on NM_001304808.3) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV99350343; called by muse, mutect2, varscan2
- DHRS9 | c.822T>G p.S274R | Missense Mutation (SNP) | VAF 171/261 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100513708; called by muse, mutect2, varscan2
- HUNK | c.1832T>A p.L611H | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV99529002; called by muse, mutect2, varscan2
- LRP1B | c.11122G>T p.D3708Y | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs200747526, COSV67237636, COSV67247383; called by muse, mutect2, varscan2
- LYAR | c.991A>T p.K331* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100603558; called by muse, mutect2, varscan2
- MAP1A | c.6082T>G p.S2028A | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100289269; called by muse, mutect2, varscan2
- PRELID3B | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.425); catalogued as COSV100582333; called by muse, mutect2, varscan2
- RIPOR1 | c.2059G>T p.E687* (on ENST00000379312 / NM_001193522.2; = p.E683* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99243686; called by muse, mutect2
- SULT1B1 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100150254, COSV100150503; called by muse, mutect2
- TTLL4 | c.3254C>A p.P1085Q | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.65); PolyPhen benign (0.205); catalogued as COSV99293773; called by muse, mutect2, varscan2
- UNC80 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 34/302 reads (11%) | catalogued as COSV99781063; called by muse, mutect2, varscan2
- ZFAND1 | c.585T>A p.F195L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV99605541; called by muse, mutect2, varscan2
- AFF1 | c.2877del p.F959Lfs*10 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- ARHGEF38 | c.32del p.N11Tfs*12 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- IGF2R | c.4913_4915del p.F1638del | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
- NLGN4X | c.1161G>A p.E387= | Silent (SNP) | VAF 82/128 reads (64%) | catalogued as COSV99324054; called by muse, mutect2, varscan2
- RTTN | c.2214C>A p.L738= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV55342084, COSV99733912; called by muse, mutect2, varscan2
